Surgical pathology report (de-identified scan), TCGA case TCGA-NC-A5HG, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Washington University - CHUV, specimen TCGA-NC-A5HG-01A (Primary Tumor).

Synoptic translated report

Site : Right lung inferior lobe

☒ Central ☐ Peripheral ☐ NA

Number of lesion :

1. Lung squamous cell carcinoma

Tumor size:

1. 4 cm (diameter)

Visceral pleural invasion: ☐ Yes ☒ No ☐ NA

Chest wall invasion : ☐ Yes ☒ No ☐ NA

Histological diagnosis : Moderately to poorly differentiated squamous cell carcinoma, basaloid variant

Node status : N 2 (3/27)

TNM : pT2 pN2 (3/27) G2-3 R0

ICD-O-3
Carcinoma, Squamous Cell basaloid
Site: B Lung, lower lobe 8083/3
C34.3
W 2/11/13

Pathologist signature:

Date:

Primary Malignancy History		✓

Source: NCI Genomic Data Commons file 38cdfc7b-d4c5-4c70-b4f2-5c49ee17c14a (TCGA-NC-A5HG.0E4B8213-E1E7-44B2-A086-F53CDE435C10.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).